Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29V, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29V-06A (Metastatic).

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Conies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Excision of melanoma skin recurrence (primary parotid area). Recurrent lesion sternum/chest.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

"LESION FROM CHEST". The specimen is unorientated skin ellipse measuring 53 x 20 x depth of 17mm, bearing a centrally located pigmented nodule measuring approximately 17 x 15mm. Surgical margin inked blue. The shave for melanoma tumour banking has been taken as a paramedian slice. Serial sectioning also shows a dark dermal nodule measuring approximately 8 x 4 x 4mm, close to one tip. Whole superficial lesion and dermal nodule embedded. Tips not embedded.

- A-D Superficial nodule.
- E Dermal nodule.
- F Tip close to dermal nodule.

100-0-3
Melanoma, No 5 8720/3
Site: skin, chest 044.5
hw 6/2/11

MICROSCOPIC REPORT

"LESION FROM CHEST".

The skin lesion shows a large nodule of melanoma consistent with recurrence/metastasis with underlying squamous cell carcinoma. The melanoma consists of small epithelioid and naevoid cells with abundant cytoplasmic pigment. The lesion is extensively ulcerated and measures 4mm in thickness. The squamous carcinoma consists of islands of tumour in the upper dermis beneath the melanoma. There is no lymphovascular or perineural invasion. There is a separate nodule of melanoma towards one pole in the deep dermis and subcutis 8mm in diameter.

Margins appear clear of each of the lesions. The ulcerated melanoma is clear by 1mm peripherally and by 15mm from the base. The dermal nodule is clear by 1mm peripherally and 4mm from the base. The squamous cell carcinoma is also clear by 6mm.

SUMMARY

SKIN OF CHEST. EXCISION BIOPSY - METASTATIC MELANOMA. EXCISED.

REPORTED BY: A Prof 1

A Unto

Pdri

Page 1 of 1

For more information		

Source: NCI Genomic Data Commons file 8c0c67a5-6c75-48c6-b5f2-e948df50c6c3 (TCGA-EE-A29V.24E328F1-3272-4386-A8B5-8E8E7CD0EE48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).